Somatic mutation profile of tumor specimen C3N-00550-02 (aliquot CPT0067620006) from CPTAC case C3N-00550, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 52.3 years (19,107 days).
Specimen C3N-00550-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b0e4158-4339-4a2e-a246-989698706e7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00550-71 (Blood Derived Normal), aliquot CPT0067850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d2ee2ed-2beb-40ba-a233-9790c2a26ff8

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Frame Shift Del 3, Intron 2, Splice Region 1, 5'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 46/184 reads (25%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.5200G>C p.E1734Q | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67996977; called by muse, mutect2
- CFAP46 | c.6779G>A p.R2260H | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs562348962, COSV99585870; called by muse, mutect2, varscan2
- CLEC2B | c.117G>T p.W39C | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947039; called by muse, mutect2
- CYP1B1 | c.1040C>A p.T347N | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV53192828; called by muse, mutect2, varscan2
- ETV6 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67149750, COSV67150692; called by muse, mutect2, varscan2
- FADS2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs199630600, COSV53902241; called by muse, mutect2, varscan2
- HES4 | c.207C>T p.S69= | Splice Region (SNP) | VAF 35/142 reads (25%) | catalogued as rs771948328; called by muse, mutect2, varscan2
- KCNC2 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54376927; called by muse, mutect2, varscan2
- KCND2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.523); catalogued as rs1044289793, COSV100474141, COSV58569920; called by muse, mutect2, varscan2
- NOB1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199699618, COSV52062785, COSV52063026; called by muse, mutect2, varscan2
- OR4Q3 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 14/349 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59180143; called by muse, mutect2
- PATL2 | c.1272G>C p.L424F | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as rs1352317369; called by muse, mutect2, varscan2
- SF3B1 | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.857); catalogued as COSV59209061; called by muse, mutect2
- TRRAP | c.7094G>A p.R2365Q (on ENST00000359863 / NM_001244580.1; = p.R2347Q on NM_003496.3) | Missense Mutation (SNP) | VAF 38/452 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs760207616, COSV62842430; called by muse, mutect2
- UBN1 | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1435565476; called by muse, mutect2
- AMBRA1 | c.726T>G p.N242K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- BNIP2 | c.552A>C p.R184S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BRSK1 | c.2146A>T p.T716S | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC150 | c.2666A>G p.K889R | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); called by muse, mutect2
- CCSER2 | c.1513G>T p.D505Y | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTNNA2 | c.2438T>C p.V813A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.062); called by muse, mutect2
- DUOX1 | c.681del p.R229Gfs*112 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- EGFR | c.1073A>G p.H358R | Missense Mutation (SNP) | VAF 92/648 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- FABP6 | c.128A>C p.K43T | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRIN3B | c.3056C>A p.P1019H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- JRKL | c.1111A>C p.M371L | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MRPL28 | c.635_639del p.I212Kfs*52 | Frame Shift Del (DEL) | VAF 21/261 reads (8%) | called by mutect2, pindel
- NLRP14 | c.3152G>A p.C1051Y | Missense Mutation (SNP) | VAF 54/433 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- POLRMT | c.2983A>T p.M995L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RGL1 | c.809A>C p.K270T (on ENST00000360851 / NM_001297672.2; = p.K305T on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- RUNX2 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TENM1 | c.1190T>G p.I397R | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); called by muse, varscan2
- TUBA3E | c.1348T>C p.Y450H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); called by mutect2, varscan2
- VEGFC | c.544_551del p.S182Vfs*3 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.5199G>A p.E1733= | Silent (SNP) | VAF 23/276 reads (8%) | catalogued as rs367929245; called by muse, mutect2
- DNAJC13 | c.735T>G p.P245= | Silent (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- GAK | c.1710C>T p.P570= | Silent (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1866A>T p.T622= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2
- RASSF7 | c.666G>A p.Q222= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as rs1206459747; called by muse, mutect2, varscan2
- SUPT20HL2 | c.288T>C p.D96= | Silent (SNP) | VAF 31/279 reads (11%) | called by muse, mutect2, varscan2
- TNC | c.69G>A p.G23= | Silent (SNP) | VAF 97/326 reads (30%) | called by muse, mutect2, varscan2
- YIF1A | c.111C>T p.P37= | Silent (SNP) | VAF 185/514 reads (36%) | catalogued as rs1197885769; called by muse, mutect2, varscan2
- ZNF114 | c.759C>T p.C253= | Silent (SNP) | VAF 55/234 reads (24%) | catalogued as rs764325220, COSV59944033; called by muse, mutect2, varscan2
- ZNF275 | c.1017C>T p.H339= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as rs372138739, COSV64704631; called by muse, mutect2
- COG6 | chr13:39655652 C>A | 5'Flank (SNP) | VAF 51/268 reads (19%) | called by muse, mutect2, varscan2
- EDN3 | c.52+13G>A | Intron (SNP) | VAF 62/178 reads (35%) | called by muse, mutect2, varscan2
- ITPRID1 | c.164-26A>G | Intron (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- ZNF44 | c.*1089T>C | 3'UTR (SNP) | VAF 25/199 reads (13%) | called by muse, mutect2, varscan2
